Somatic mutation profile of tumor specimen C3N-01646-01 (aliquot CPT0088480009) from CPTAC case C3N-01646, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 69.9 years (25,523 days).
Specimen C3N-01646-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e9190b14-d49a-4760-a2e8-3e5419131426.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01646-31 (Blood Derived Normal), aliquot CPT0088540001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a031a414-3aa3-4740-bf77-f60f0eb299a1

The open-access MAF lists 149 somatic variants for this specimen: 106 protein-altering or splice-affecting, 26 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 75, Silent 26, Frame Shift Del 14, Intron 7, RNA 7, Nonsense Mutation 5, Splice Region 3, In Frame Del 3, Splice Site 3, Frame Shift Ins 2, 5'UTR 2, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY4 | c.3035A>G p.N1012S | Missense Mutation (SNP) | VAF 50/205 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as COSV60254617; called by muse, mutect2, varscan2
- ADGRB2 | c.4292G>A p.S1431N | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as rs903699702; called by muse, mutect2, varscan2
- ARHGEF37 | c.803A>C p.E268A | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.457); catalogued as rs1404405373; called by muse, mutect2, varscan2
- CACNG7 | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as rs1173224176, COSV55816209, COSV99712051; called by muse, mutect2, varscan2
- CCNL1 | c.378+8C>T | Splice Region (SNP) | VAF 36/203 reads (18%) | catalogued as rs888495652; called by muse, mutect2, varscan2
- CD1C | c.474G>T p.L158F | Missense Mutation (SNP) | VAF 85/433 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV100939472, COSV63807331; called by muse, mutect2, varscan2
- CELSR1 | c.4341C>A p.F1447L | Missense Mutation (SNP) | VAF 50/196 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53094821; called by muse, mutect2, varscan2
- CRTC3 | c.707C>G p.S236C | Missense Mutation (SNP) | VAF 32/238 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV51601452; called by muse, mutect2, varscan2
- CSMD3 | c.3832G>A p.G1278R (on ENST00000297405 / NM_001363185.1; = p.G1174R on NM_052900.3) | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52165357, COSV99847243; called by muse, mutect2, varscan2
- CXCL12 | c.105C>G p.F35L | Missense Mutation (SNP) | VAF 56/306 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0.099); catalogued as COSV100639090, COSV59108018; called by muse, mutect2, varscan2
- DISC1 | c.1960G>A p.E654K | Missense Mutation (SNP) | VAF 34/216 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs1312422790; called by muse, mutect2, varscan2
- FBXO17 | c.696C>G p.V232= | Splice Region (SNP) | VAF 7/64 reads (11%) | catalogued as rs1474934134, COSV53071509; called by muse, mutect2, varscan2
- IRAK1 | c.1455C>G p.C485W | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64110000; called by muse, mutect2, varscan2
- NF1 | c.731-1G>T p.X244_splice | Splice Site (SNP) | VAF 63/275 reads (23%) | catalogued as CS086352, CS086353, CS094454, COSV62191398; called by muse, mutect2, varscan2
- NF1 | c.2851-1G>A p.X951_splice | Splice Site (SNP) | VAF 28/135 reads (21%) | catalogued as CD000081, CS1311517, COSV62220039; called by muse, mutect2, varscan2
- NTF4 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 52/239 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs1220929905, COSV100032250; called by muse, mutect2, varscan2
- PDXK | c.131C>T p.S44L | Missense Mutation (SNP) | VAF 67/319 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52364413; called by muse, mutect2, varscan2
- PIEZO1 | c.3931A>G p.R1311G | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs941138321; called by muse, mutect2, varscan2
- PKMYT1 | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.212); catalogued as rs1407927917; called by muse, mutect2, varscan2
- POLD1 | c.632G>C p.R211P | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs373192520, COSV70955161; called by muse, mutect2, varscan2
- RALBP1 | c.387del p.K130Nfs*25 | Frame Shift Del (DEL) | VAF 10/63 reads (16%) | catalogued as COSV50034298; called by mutect2, pindel, varscan2
- RPS6KC1 | c.563C>G p.S188C | Missense Mutation (SNP) | VAF 39/180 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV65297355; called by muse, mutect2, varscan2
- TEX15 | c.5122dup p.R1708Kfs*6 (on ENST00000256246; = p.R2091Kfs*6 on NM_001350162.2) | Frame Shift Ins (INS) | VAF 10/68 reads (15%) | catalogued as rs778104055; called by mutect2, varscan2
- TP53BP1 | c.2828G>A p.S943N | Missense Mutation (SNP) | VAF 42/181 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.073); catalogued as rs1325641515; called by muse, mutect2, varscan2
- TUBB4A | c.1115C>T p.T372M | Missense Mutation (SNP) | VAF 142/757 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as rs1203178469; called by muse, mutect2, varscan2
- UGT2B4 | c.1042G>A p.G348R | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59320451; called by muse, mutect2, varscan2
- ZC3H4 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 67/390 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV53415158; called by muse, mutect2, varscan2
- ZNF511 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 77/282 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.247); catalogued as rs746249082, COSV100756872; called by muse, mutect2, varscan2
- ZNF729 | c.3322G>A p.E1108K | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs777377001; called by muse, mutect2, varscan2
- ABCD2 | c.857C>T p.A286V | Missense Mutation (SNP) | VAF 55/264 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADM | c.307C>T p.Q103* | Nonsense Mutation (SNP) | VAF 61/300 reads (20%) | called by muse, mutect2, varscan2
- ANXA13 | c.152A>C p.Q51P | Missense Mutation (SNP) | VAF 32/191 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- ARHGEF19 | c.257A>T p.D86V | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- ARID4B | c.2458A>G p.I820V | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATXN2L | c.1877C>T p.P626L | Missense Mutation (SNP) | VAF 65/256 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- BABAM2 | c.173T>C p.L58P | Missense Mutation (SNP) | VAF 59/273 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- BAP1 | c.83_85del p.Q28_V29delinsL | In Frame Del (DEL) | VAF 150/497 reads (30%) | called by mutect2, pindel, varscan2
- CAMK1 | c.753T>A p.D251E | Missense Mutation (SNP) | VAF 43/190 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- CD151 | c.167C>T p.T56I | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- CEP152 | c.2065A>T p.I689L | Missense Mutation (SNP) | VAF 136/653 reads (21%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CFAP43 | c.741del p.D248Mfs*30 | Frame Shift Del (DEL) | VAF 24/100 reads (24%) | called by mutect2, pindel
- CHD2 | c.1251G>T p.W417C | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHRM2 | c.636del p.S213Afs*5 | Frame Shift Del (DEL) | VAF 143/635 reads (23%) | called by mutect2, pindel*, varscan2*
- CTNND2 | c.1682A>T p.H561L | Missense Mutation (SNP) | VAF 59/262 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- EEF2K | c.2032G>A p.G678R | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EFCAB13 | c.1510G>A p.E504K | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, varscan2
- ELP2 | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 58/357 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.006); called by muse, mutect2
- ENO3 | c.633_651del p.G212Wfs*10 | Frame Shift Del (DEL) | VAF 61/375 reads (16%) | called by mutect2, pindel, varscan2
- ENPP3 | c.2498C>A p.T833K | Missense Mutation (SNP) | VAF 49/174 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- EVI2B | c.125C>G p.S42* | Nonsense Mutation (SNP) | VAF 44/232 reads (19%) | called by muse, varscan2
- GBE1 | c.1934+2del p.X645_splice | Splice Site (DEL) | VAF 26/139 reads (19%) | called by mutect2, pindel, varscan2
- GLRB | c.554del p.L185Wfs*3 | Frame Shift Del (DEL) | VAF 55/238 reads (23%) | called by mutect2, pindel, varscan2
- HECTD4 | c.3023C>A p.T1008K | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- HFM1 | c.85G>C p.E29Q | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- IFNAR2 | c.1405C>A p.H469N | Missense Mutation (SNP) | VAF 74/353 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ITGA11 | c.1212del p.P405Lfs*7 | Frame Shift Del (DEL) | VAF 51/326 reads (16%) | called by mutect2, pindel, varscan2
- ITPKC | c.1940A>C p.D647A | Missense Mutation (SNP) | VAF 53/293 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- LPAR3 | c.460G>T p.A154S | Missense Mutation (SNP) | VAF 63/302 reads (21%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- LRRC41 | c.1610T>C p.L537P | Missense Mutation (SNP) | VAF 102/482 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- LSM12 | c.584C>G p.S195C | Missense Mutation (SNP) | VAF 39/191 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- MAGOH | c.386T>C p.L129P | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MMP2 | c.274A>C p.N92H | Missense Mutation (SNP) | VAF 105/448 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- MR1 | c.634G>C p.E212Q | Missense Mutation (SNP) | VAF 55/189 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- MROH1 | c.1765T>C p.Y589H | Missense Mutation (SNP) | VAF 35/170 reads (21%) | SIFT tolerated (0.88); PolyPhen benign (0.001); called by muse, mutect2
- MTMR9 | c.748G>A p.G250S | Missense Mutation (SNP) | VAF 82/447 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- MUC6 | c.6387del p.S2130Hfs*46 | Frame Shift Del (DEL) | VAF 54/264 reads (20%) | called by mutect2, pindel, varscan2
- MYO1D | c.949del p.Y317Tfs*100 | Frame Shift Del (DEL) | VAF 104/528 reads (20%) | called by mutect2, pindel, varscan2
- NHEJ1 | c.666del p.T223Hfs*32 | Frame Shift Del (DEL) | VAF 90/409 reads (22%) | called by mutect2, varscan2
- NOP53 | c.431A>G p.K144R | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- NSD1 | c.7849_7861del p.L2617Sfs*19 | Frame Shift Del (DEL) | VAF 43/247 reads (17%) | called by mutect2, pindel, varscan2
- OSBPL7 | c.195G>T p.W65C | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PARP10 | c.12G>T p.M4I | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- PELI2 | c.349A>T p.T117S | Missense Mutation (SNP) | VAF 62/262 reads (24%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.989); called by muse, varscan2
- PELI2 | c.361del p.S121Lfs*72 | Frame Shift Del (DEL) | VAF 70/326 reads (21%) | called by pindel, varscan2
- PNPLA3 | c.1135A>G p.M379V | Missense Mutation (SNP) | VAF 45/202 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- POU3F3 | c.1412A>T p.Q471L | Missense Mutation (SNP) | VAF 78/341 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PPP1R3G | c.818_819del p.E273Afs*40 | Frame Shift Del (DEL) | VAF 64/312 reads (21%) | called by mutect2, pindel, varscan2
- PSMD2 | c.1911G>T p.K637N | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- RAB38 | c.100T>C p.F34L | Missense Mutation (SNP) | VAF 62/356 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- RALY | c.839A>G p.D280G (on ENST00000246194 / NM_016732.3; = p.D264G on NM_007367.4) | Missense Mutation (SNP) | VAF 36/180 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- RCN3 | c.375_376del p.Y125* | Nonsense Mutation (DEL) | VAF 12/51 reads (24%) | called by mutect2, pindel, varscan2
- RFX1 | c.2597T>A p.L866Q | Missense Mutation (SNP) | VAF 35/183 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RHAG | c.580C>G p.L194V | Missense Mutation (SNP) | VAF 92/449 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- RNF151 | c.117C>A p.F39L | Missense Mutation (SNP) | VAF 36/146 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RPL23A | c.281_283del p.N94del | In Frame Del (DEL) | VAF 76/411 reads (18%) | called by pindel, varscan2
- RPUSD2 | c.493_495del p.V165del | In Frame Del (DEL) | VAF 50/266 reads (19%) | called by mutect2, pindel, varscan2
- RSF1 | c.1729A>T p.K577* | Nonsense Mutation (SNP) | VAF 41/213 reads (19%) | called by muse, mutect2, varscan2
- SCN8A | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.028); called by muse, mutect2
- SEL1L2 | c.1923G>T p.L641F | Missense Mutation (SNP) | VAF 67/221 reads (30%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- SGSH | c.1354G>C p.A452P | Missense Mutation (SNP) | VAF 135/709 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- SIPA1L1 | c.1966_1967del p.K656Vfs*6 | Frame Shift Del (DEL) | VAF 70/251 reads (28%) | called by mutect2, pindel, varscan2
- SLC6A5 | c.1142A>T p.K381M | Missense Mutation (SNP) | VAF 125/563 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- SLC7A13 | c.946C>A p.L316I | Missense Mutation (SNP) | VAF 35/177 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLITRK5 | c.1205C>T p.A402V | Missense Mutation (SNP) | VAF 35/195 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SPNS2 | c.880G>C p.D294H | Missense Mutation (SNP) | VAF 45/219 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SPTY2D1 | c.1413T>A p.S471R | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- STK32C | c.113C>G p.P38R | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.652); called by muse, varscan2
- TMEM59 | c.390+5G>T | Splice Region (SNP) | VAF 41/223 reads (18%) | called by muse, mutect2, varscan2
- TRAF3IP3 | c.995T>A p.L332H | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- TREML2 | c.928G>A p.G310R | Missense Mutation (SNP) | VAF 39/269 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP4 | c.1762A>T p.K588* | Nonsense Mutation (SNP) | VAF 41/142 reads (29%) | called by muse, mutect2, varscan2
- UTP14C | c.678_679insTTT p.L226_Q227insF | In Frame Ins (INS) | VAF 88/431 reads (20%) | called by mutect2, pindel, varscan2
- VPS37C | c.278dup p.A94Sfs*27 | Frame Shift Ins (INS) | VAF 49/217 reads (23%) | called by mutect2, pindel, varscan2
- VSIR | c.559_563del p.D187* | Frame Shift Del (DEL) | VAF 48/248 reads (19%) | called by mutect2, pindel, varscan2
- ZNF224 | c.587G>A p.R196K | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- ZNF534 | c.901C>T p.H301Y (on ENST00000332323 / NM_001143939.3; = p.H288Y on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CFAP54 | c.6261A>G p.L2087= | Silent (SNP) | VAF 24/106 reads (23%) | called by muse, mutect2, varscan2
- CHAF1B | c.192T>A p.R64= | Silent (SNP) | VAF 50/244 reads (20%) | called by muse, mutect2, varscan2
- EIF2S3B | c.78C>G p.T26= | Silent (SNP) | VAF 95/434 reads (22%) | called by muse, mutect2, varscan2
- EXPH5 | c.516T>A p.P172= | Silent (SNP) | VAF 38/161 reads (24%) | catalogued as rs1218006345; called by muse, mutect2, varscan2
- FHOD3 | c.2526C>T p.P842= (on ENST00000359247 / NM_001281739.3; = p.P859= on NM_025135.5) | Silent (SNP) | VAF 22/124 reads (18%) | catalogued as COSV99942477; called by muse, varscan2
- FKBP10 | c.1701C>A p.L567= | Silent (SNP) | VAF 88/504 reads (17%) | catalogued as COSV54057514; called by muse, mutect2, varscan2
- GLI2 | c.1210C>T p.L404= (on ENST00000361492 / NM_001374353.1; = p.L421= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 77/379 reads (20%) | called by muse, mutect2, varscan2
- GZF1 | c.339T>C p.A113= | Silent (SNP) | VAF 41/165 reads (25%) | called by muse, mutect2, varscan2
- HJV | c.561C>T p.V187= (on ENST00000336751 / NM_213653.4; = p.V74= on NM_145277.5) | Silent (SNP) | VAF 80/511 reads (16%) | called by muse, mutect2, varscan2
- ILF3 | c.2613C>T p.P871= | Silent (SNP) | VAF 30/112 reads (27%) | called by muse, mutect2, varscan2
- MAST4 | c.5688C>T p.F1896= (on ENST00000403625 / NM_001164664.2; = p.F1707= on NM_015183.3) | Silent (SNP) | VAF 32/159 reads (20%) | catalogued as rs964081653; called by muse, mutect2, varscan2
- MBD3L2 | c.601C>A p.R201= | Silent (SNP) | VAF 112/593 reads (19%) | catalogued as rs185575432; called by muse, mutect2, varscan2
- MON2 | c.3381C>T p.N1127= | Silent (SNP) | VAF 90/406 reads (22%) | called by muse, mutect2, varscan2
- MRGPRX1 | c.801C>T p.A267= | Silent (SNP) | VAF 52/205 reads (25%) | called by muse, mutect2, varscan2
- MRPS5 | c.945C>T p.R315= | Silent (SNP) | VAF 37/154 reads (24%) | called by muse, mutect2, varscan2
- MUC5B | c.1608G>A p.L536= | Silent (SNP) | VAF 33/120 reads (28%) | called by muse, mutect2, varscan2
- NLRP1 | c.4410A>T p.P1470= (on ENST00000572272 / NM_033004.4; = p.P1426= on NM_014922.5) | Silent (SNP) | VAF 35/146 reads (24%) | catalogued as COSV52580753; called by muse, varscan2
- NXNL1 | c.399C>A p.L133= | Silent (SNP) | VAF 30/152 reads (20%) | called by muse, mutect2, varscan2
- POM121 | c.30A>G p.A10= | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as rs1554496809; called by muse, mutect2, varscan2
- PRKCZ | c.930C>T p.N310= | Silent (SNP) | VAF 39/297 reads (13%) | called by muse, mutect2, varscan2
- SHISA3 | c.447C>A p.I149= | Silent (SNP) | VAF 108/529 reads (20%) | called by muse, varscan2
- SNAPC4 | c.2973T>A p.P991= | Silent (SNP) | VAF 21/58 reads (36%) | called by muse, mutect2, varscan2
- SORBS3 | c.909G>A p.S303= | Silent (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2, varscan2
- TTC28 | c.5016C>T p.F1672= | Silent (SNP) | VAF 49/322 reads (15%) | called by muse, mutect2, varscan2
- VWA3A | c.1734C>T p.A578= | Silent (SNP) | VAF 11/74 reads (15%) | called by muse, mutect2, varscan2
- ZIM3 | c.882C>A p.L294= | Silent (SNP) | VAF 21/149 reads (14%) | called by muse, mutect2, varscan2
- BEND6 | c.299-616T>A | Intron (SNP) | VAF 6/36 reads (17%) | called by muse, mutect2, varscan2
- C12orf76 | n.766_782del | RNA (DEL) | VAF 41/169 reads (24%) | called by mutect2, pindel, varscan2
- CDHR3 | c.2273-73G>A | Intron (SNP) | VAF 39/170 reads (23%) | catalogued as rs532208849; called by muse, mutect2, varscan2
- DIDO1 | c.1588+25T>A | Intron (SNP) | VAF 72/292 reads (25%) | called by muse, mutect2, varscan2
- FAM104B | c.20+194T>C | Intron (SNP) | VAF 79/207 reads (38%) | called by muse, mutect2, varscan2
- GUSBP1 | n.77A>G | RNA (SNP) | VAF 69/371 reads (19%) | catalogued as rs1199895139; called by muse, mutect2, varscan2
- GVINP1 | n.6581A>T | RNA (SNP) | VAF 16/65 reads (25%) | called by muse, mutect2, varscan2
- LINC01948 | n.466G>C | RNA (SNP) | VAF 37/230 reads (16%) | called by muse, mutect2, varscan2
- NAPB | c.-31T>C | 5'UTR (SNP) | VAF 23/115 reads (20%) | called by muse, mutect2, varscan2
- NEIL1 | c.874+15A>G | Intron (SNP) | VAF 32/190 reads (17%) | called by muse, mutect2, varscan2
- PA2G4 | c.-3A>G | 5'UTR (SNP) | VAF 58/313 reads (19%) | called by muse, mutect2, varscan2
- PLEKHA8P1 | n.866del | RNA (DEL) | VAF 38/179 reads (21%) | called by mutect2, pindel, varscan2
- SDHAP2 | n.897A>G | RNA (SNP) | VAF 53/1072 reads (5%) | catalogued as rs756725887; called by muse, mutect2
- SNORD114-1 | n.8A>G | RNA (SNP) | VAF 29/109 reads (27%) | catalogued as rs1488804835; called by muse, mutect2, varscan2
- SPEG | c.389-633_389-620delinsA | Intron (DEL) | VAF 58/301 reads (19%) | called by pindel, varscan2*
- TMPRSS6 | c.-2+15C>T | Intron (SNP) | VAF 123/523 reads (24%) | called by muse, mutect2, varscan2
- ZNF44 | c.*421_*422del | 3'UTR (DEL) | VAF 36/154 reads (23%) | called by mutect2, pindel, varscan2
